Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4976, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4976-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

TCGA-BP-4976

Clinical Diagnosis & History:

With right renal mass.

Specimens Submitted:

1: SP: Kidney, right renal tumor, partial nephrectomy

DIAGNOSIS:

1. SP: Kidney, right renal tumor, partial nephrectomy (m):

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 4.0 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh for intraoperative consultation and is labeled "right renal tumor. Please freeze, deep margin stitch marks deep margin". It consists of a 4.6 x 3.7 x 3.0 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal 4.0 by 3.5 x 3.5 cm tan yellow hemorrhagic mass. The clearance from the resection margin is 0.1 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control

T - tumor

M - margin

Summary of Sections:

Part 1: SP: Kidney, right renal tumor, partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
1	m	1
2	t	2

Intraoperative Consultation:

The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL EPITHELIAL NEOPLASM, SUTURED MARGIN FREE.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file a29c559a-460f-4867-b8af-a3442e99a1ff (TCGA-BP-4976.B2364F79-2C5E-483F-ADE0-8865F5B71A8D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).